Somatic mutation profile of tumor specimen TCGA-D8-A27L-01A (aliquot TCGA-D8-A27L-01A-11D-A16D-09) from TCGA case TCGA-D8-A27L, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 49.3 years (18,025 days).
Specimen TCGA-D8-A27L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b529c0a-c428-4586-99cc-40c72e8e2d8f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27L-10A (Blood Derived Normal), aliquot TCGA-D8-A27L-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b12843ce-1349-4f91-a4aa-cd822600c0a1

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 28, Silent 11, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP1 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 82/362 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs869025203, CM1514549, COSV59538312; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/86 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.46dup p.Y16Lfs*28 | Frame Shift Ins (INS) | VAF 32/139 reads (23%) | catalogued as rs786204883, COSV64299384; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATP13A2 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as rs754208001, COSV58699445; called by muse, mutect2
- AZI2 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV55423544; called by muse, mutect2, varscan2
- C5orf22 | c.993-1G>A p.X331_splice | Splice Site (SNP) | VAF 47/200 reads (24%) | catalogued as COSV57597956; called by muse, mutect2, varscan2
- CAD | c.1352A>G p.Y451C | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs770953907, COSV53025097; called by muse, mutect2, varscan2
- CIR1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 15/265 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs200291230, COSV59595809; called by muse, mutect2
- CPNE3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as rs1307411225, COSV99547759; called by muse, mutect2
- FAM131B | c.292C>G p.Q98E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.084); catalogued as COSV68125722; called by muse, mutect2, varscan2
- FN1 | c.7147G>A p.D2383N (on ENST00000359671 / NM_001365524.2; = p.D2352N on NM_002026.4) | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV100117364; called by muse, mutect2
- FRMPD4 | c.3607C>A p.Q1203K | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66213099; called by muse, mutect2, varscan2
- KANSL3 | c.2254C>G p.Q752E (on ENST00000666923 / NM_001349262.2; = p.Q726E on NM_001115016.3) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.281); catalogued as COSV62616395; called by muse, mutect2, varscan2
- KAT8 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54895930; called by muse, mutect2, varscan2
- KDM3A | c.2647G>A p.G883S | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.349); catalogued as COSV57219756; called by muse, mutect2, varscan2
- KMT2C | c.3674C>G p.S1225* | Nonsense Mutation (SNP) | VAF 18/200 reads (9%) | catalogued as COSV100073155; called by muse, mutect2
- MAP3K1 | c.3918_3920del p.I1307del | In Frame Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs1357146419; called by pindel, varscan2
- NAV1 | c.3557C>G p.S1186* | Nonsense Mutation (SNP) | VAF 9/74 reads (12%) | catalogued as COSV55215776; called by muse, mutect2, varscan2
- NEIL1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.201); catalogued as COSV61833239; called by muse, mutect2, varscan2
- NPAS1 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV71383920; called by muse, mutect2, varscan2
- OR1L6 | c.377C>T p.T126I (on ENST00000373684; = p.T90I on NM_001004453.2) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV100490917, COSV59028071; called by muse, mutect2
- OTUB1 | c.404T>C p.I135T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); catalogued as COSV55358711; called by muse, mutect2, varscan2
- PCDHB9 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781872921, COSV53376606; called by muse, mutect2
- PCDHGB6 | c.652G>A p.G218R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53921669, COSV53938112; called by muse, mutect2, varscan2
- PPRC1 | c.4568C>T p.S1523L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV53384235; called by muse, mutect2, varscan2
- RERE | c.1313G>A p.W438* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV61940114; called by muse, mutect2, varscan2
- SGK2 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV58312650; called by muse, mutect2, varscan2
- STK35 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99852916; called by muse, mutect2
- SULT2B1 | c.806G>A p.R269H (on ENST00000201586 / NM_177973.2; = p.R254H on NM_004605.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1487610540, COSV52374788; called by muse, mutect2
- TMPRSS6 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.089); catalogued as rs1270960721, COSV60976662; called by muse, mutect2, varscan2
- WAS | c.1400T>G p.V467G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100939505; called by muse, mutect2
- ZNF254 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as COSV60053960; called by muse, mutect2, varscan2
- ZNF417 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 23/192 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776841345, COSV56307930; called by muse, mutect2, varscan2
- ZNF711 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV99341240; called by muse, mutect2
- MAP3K1 | c.3867dup p.A1290Sfs*19 | Frame Shift Ins (INS) | VAF 16/87 reads (18%) | called by pindel, varscan2
- ANK2 | c.657C>T p.D219= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs761137041, COSV52152563, COSV52153636; ClinVar: likely benign; called by muse, mutect2, varscan2
- KMT2A | c.3555G>A p.K1185= | Silent (SNP) | VAF 7/93 reads (8%) | catalogued as COSV100629090; called by muse, mutect2
- LRRC15 | c.1155C>T p.F385= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs866660377, COSV61649819; called by muse, varscan2
- LRRC15 | c.1023G>A p.T341= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs761107806, COSV61649824; called by muse, varscan2
- NES | c.2265G>A p.L755= | Silent (SNP) | VAF 7/133 reads (5%) | catalogued as COSV100957895, COSV63961012; called by muse, mutect2
- OR10J3 | c.189C>T p.F63= | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as COSV100171770; called by muse, mutect2
- PAK3 | c.216T>A p.L72= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as COSV53272483; called by muse, mutect2, varscan2
- RHOT2 | c.1767C>T p.F589= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV54807982; called by muse, mutect2, varscan2
- TTC30B | c.408A>G p.V136= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs749491973, COSV68809795; called by muse, mutect2, varscan2
- ZDBF2 | c.6747G>C p.L2249= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV65630150; called by muse, mutect2, varscan2
- ZNF483 | c.327G>A p.R109= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV58515140, COSV58516839; called by muse, mutect2, varscan2
